Somatic mutation profile of tumor specimen RC-B555-TTP1-A (aliquot RC-B555-TTP1-A-1-0-D-A93N-47) from RC case RC-B555, project RC-PTCL: Refractory Cancers (RC) - Peripheral T-Cell Lymphoma (PTCL). Sex at birth: female; Vital status: Alive; Primary diagnosis: Mature T-cell lymphoma, NOS; Tissue or organ of origin: Lymph nodes of head, face and neck; Age at diagnosis: 54.2 years (19,790 days).
Specimen RC-B555-TTP1-A: Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 2d1dc954-d959-44b5-8803-77acd22cd31a.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen RC-B555-NM1-A (Bone Marrow Components NOS; tissue type Normal), aliquot RC-B555-NM1-A-1-0-D-A93N-47; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/04bddd7b-1d00-461a-83eb-dbfdbb489e30

The open-access MAF lists 57 somatic variants for this specimen: 41 protein-altering or splice-affecting, 12 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 37, Silent 12, Frame Shift Del 2, Intron 2, Nonsense Mutation 1, Nonstop Mutation 1, RNA 1, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ADAMTS16 | c.2633G>A p.R878H | Missense Mutation (SNP) | VAF 54/142 reads (38%) | SIFT tolerated (0.22); PolyPhen benign (0.006); catalogued as rs775791158, COSV99940809; called by muse, mutect2, varscan2
- ATP11B | c.2291T>C p.V764A | Missense Mutation (SNP) | VAF 40/104 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.648); catalogued as rs781551359; called by muse, mutect2, varscan2
- AVPR1B | c.832C>T p.R278* | Nonsense Mutation (SNP) | VAF 48/132 reads (36%) | catalogued as rs782036021, COSV65638796; called by muse, mutect2, varscan2
- CCDC170 | c.1693G>A p.D565N | Missense Mutation (SNP) | VAF 11/86 reads (13%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.616); catalogued as rs753228753, COSV53344384; called by muse, mutect2, varscan2
- EPHA7 | c.109G>A p.D37N | Missense Mutation (SNP) | VAF 25/72 reads (35%) | SIFT tolerated (0.13); PolyPhen benign (0.399); catalogued as COSV65170319; called by muse, mutect2, varscan2
- H3C7 | c.358A>T p.I120F | Missense Mutation (SNP) | VAF 70/163 reads (43%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.898); catalogued as COSV99769198; called by muse, mutect2, varscan2
- HOXA13 | c.850G>A p.G284S | Missense Mutation (SNP) | VAF 38/111 reads (34%) | SIFT tolerated (0.11); PolyPhen benign (0.364); catalogued as rs772451529; called by muse, mutect2, varscan2
- IGHV3-16 | c.254G>A p.R85H | Missense Mutation (SNP) | VAF 13/85 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.018); catalogued as rs782549613; called by muse, mutect2, varscan2
- KCNT2 | c.2912C>A p.S971Y | Missense Mutation (SNP) | VAF 26/64 reads (41%) | SIFT tolerated (0.13); PolyPhen benign (0.183); catalogued as COSV54065101; called by muse, mutect2, varscan2
- PACS1 | c.712G>A p.V238M | Missense Mutation (SNP) | VAF 23/128 reads (18%) | SIFT tolerated (0.26); PolyPhen benign (0.33); catalogued as rs377164490; called by muse, mutect2, varscan2
- SEC16B | c.943C>G p.L315V | Missense Mutation (SNP) | VAF 18/98 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.834); catalogued as COSV57623600; called by muse, mutect2, varscan2
- SEL1L3 | c.1265G>A p.R422H | Missense Mutation (SNP) | VAF 7/143 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV99340387; called by muse, mutect2
- SLC19A1 | c.812C>G p.S271C | Missense Mutation (SNP) | VAF 41/120 reads (34%) | SIFT tolerated (0.06); PolyPhen benign (0.211); catalogued as COSV60756410; called by muse, mutect2, varscan2
- TONSL | c.1201G>A p.E401K | Missense Mutation (SNP) | VAF 51/113 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs145310042; called by muse, mutect2, varscan2
- TPO | c.2284C>T p.R762C | Missense Mutation (SNP) | VAF 22/192 reads (11%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.719); catalogued as rs771561271; called by muse, mutect2
- WDR17 | c.1523G>A p.R508Q | Missense Mutation (SNP) | VAF 29/58 reads (50%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.99); catalogued as rs753862798, COSV54578575; called by muse, mutect2, varscan2
- WEE2 | c.1207G>A p.E403K | Missense Mutation (SNP) | VAF 51/141 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV66878561; called by muse, mutect2, varscan2
- CAV2 | c.487T>C p.*163Rext*19 | Nonstop Mutation (SNP) | VAF 46/126 reads (37%) | called by muse, mutect2, varscan2
- CYFIP2 | c.3046G>A p.D1016N (on ENST00000616178 / NM_001291722.2; = p.D991N on NM_014376.4) | Missense Mutation (SNP) | VAF 15/108 reads (14%) | SIFT tolerated (0.32); PolyPhen probably damaging (0.959); called by muse, mutect2, varscan2
- DLGAP1 | c.1549C>G p.P517A | Missense Mutation (SNP) | VAF 54/121 reads (45%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.967); called by muse, mutect2, varscan2
- DSC1 | c.1124T>C p.M375T | Missense Mutation (SNP) | VAF 14/95 reads (15%) | SIFT deleterious (0.02); PolyPhen benign (0.389); called by muse, mutect2
- F5 | c.5335A>C p.K1779Q | Missense Mutation (SNP) | VAF 33/89 reads (37%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.878); called by muse, mutect2, varscan2
- F8 | c.2960A>G p.E987G | Missense Mutation (SNP) | VAF 55/131 reads (42%) | SIFT deleterious (0.04); PolyPhen benign (0.118); called by muse, mutect2, varscan2
- FADS6 | c.239C>T p.P80L | Missense Mutation (SNP) | VAF 15/136 reads (11%) | SIFT tolerated (0.14); PolyPhen benign (0.048); called by muse, mutect2
- FBN1 | c.6071G>T p.C2024F | Missense Mutation (SNP) | VAF 27/65 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.915); called by muse, mutect2, varscan2
- FYN | c.1570_1574del p.F524Rfs*10 | Frame Shift Del (DEL) | VAF 36/105 reads (34%) | called by mutect2, pindel, varscan2
- GPR33 | c.530T>C p.V177A | Missense Mutation (SNP) | VAF 57/148 reads (39%) | SIFT deleterious (0); PolyPhen benign (0.318); called by muse, mutect2, varscan2
- IGSF21 | c.421A>C p.M141L | Missense Mutation (SNP) | VAF 33/86 reads (38%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.558); called by muse, mutect2, varscan2
- IPO4 | c.1304A>C p.E435A | Missense Mutation (SNP) | VAF 46/93 reads (49%) | SIFT deleterious (0.01); PolyPhen benign (0.201); called by muse, mutect2, varscan2
- MET | c.611C>T p.S204F | Missense Mutation (SNP) | VAF 39/106 reads (37%) | SIFT deleterious (0); PolyPhen benign (0.164); called by muse, mutect2, varscan2
- MSI1 | c.688C>T p.R230W | Missense Mutation (SNP) | VAF 35/87 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- NLGN4X | c.2296C>T p.R766W | Missense Mutation (SNP) | VAF 74/187 reads (40%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- OR4F17 | c.8C>T p.T3I | Missense Mutation (SNP) | VAF 58/261 reads (22%) | SIFT deleterious (0); PolyPhen benign (0.207); called by muse, mutect2, varscan2
- PCDH15 | c.414A>T p.R138S | Missense Mutation (SNP) | VAF 34/84 reads (40%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.503); called by muse, mutect2, varscan2
- PRDM9 | c.839T>A p.I280N | Missense Mutation (SNP) | VAF 49/123 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.641); called by muse, mutect2, varscan2
- RAB44 | c.1714A>T p.T572S | Missense Mutation (SNP) | VAF 56/151 reads (37%) | SIFT tolerated, low confidence (0.66); PolyPhen probably damaging (0.97); called by muse, mutect2
- RSBN1L | c.2473G>A p.V825I | Missense Mutation (SNP) | VAF 52/125 reads (42%) | SIFT tolerated, low confidence (0.38); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- SEMA3F | c.298C>T p.R100C | Missense Mutation (SNP) | VAF 43/107 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); called by muse, mutect2, varscan2
- SP8 | c.628T>G p.W210G (on ENST00000361443 / NM_198956.4; = p.W228G on NM_182700.6) | Missense Mutation (SNP) | VAF 52/131 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.649); called by muse, mutect2, varscan2
- SPIDR | c.158G>C p.G53A | Missense Mutation (SNP) | VAF 40/100 reads (40%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- THBS1 | c.291del p.M97Ifs*36 | Frame Shift Del (DEL) | VAF 39/149 reads (26%) | called by mutect2, pindel, varscan2
- AMOTL2 | c.2208C>T p.S736= (on ENST00000422605; = p.S737= on NM_016201.4) | Silent (SNP) | VAF 68/173 reads (39%) | called by muse, mutect2
- CCDC88B | c.2289C>G p.A763= | Silent (SNP) | VAF 42/125 reads (34%) | called by muse, mutect2, varscan2
- CILP2 | c.1359C>T p.Y453= | Silent (SNP) | VAF 67/152 reads (44%) | catalogued as rs374632386; called by muse, mutect2, varscan2
- GDF7 | c.189G>A p.P63= | Silent (SNP) | VAF 5/16 reads (31%) | catalogued as rs1386503371; called by muse, mutect2, varscan2
- IGSF10 | c.7065A>G p.T2355= | Silent (SNP) | VAF 47/128 reads (37%) | called by muse, mutect2, varscan2
- NRG1 | c.243C>T p.P81= (on ENST00000523534; = p.P228= on NM_013962.2) | Silent (SNP) | VAF 21/112 reads (19%) | catalogued as rs369826756; called by muse, mutect2, varscan2
- OR4E1 | c.42A>G p.T14= | Silent (SNP) | VAF 38/118 reads (32%) | called by muse, mutect2, varscan2
- PCSK5 | c.2658G>A p.Q886= | Silent (SNP) | VAF 47/138 reads (34%) | catalogued as rs895027308; called by muse, mutect2, varscan2
- PPP3CA | c.1302C>T p.S434= | Silent (SNP) | VAF 41/97 reads (42%) | catalogued as rs369318194; called by muse, mutect2, varscan2
- SLC16A2 | c.1161C>T p.I387= | Silent (SNP) | VAF 8/130 reads (6%) | called by muse, mutect2
- WNK2 | c.6318G>A p.V2106= (on ENST00000297954 / NM_001282394.1; = p.V2069= on NM_006648.3) | Silent (SNP) | VAF 7/79 reads (9%) | called by muse, mutect2
- ZNF483 | c.1635T>C p.H545= | Silent (SNP) | VAF 52/133 reads (39%) | called by muse, mutect2, varscan2
- CFAP157 | c.1138-55G>A | Intron (SNP) | VAF 54/125 reads (43%) | catalogued as rs756900403; called by muse, mutect2, varscan2
- DENND2B | c.-25-15948C>T | Intron (SNP) | VAF 15/121 reads (12%) | catalogued as rs921934875; called by muse, mutect2, varscan2
- FP325317.2 | n.897C>T | RNA (SNP) | VAF 11/61 reads (18%) | catalogued as rs1470146663; called by muse, mutect2, varscan2
- RAB5IF | c.*113G>A | 3'UTR (SNP) | VAF 32/131 reads (24%) | catalogued as rs534176887; called by muse, mutect2, varscan2
